Somatic mutation profile of tumor specimen TCGA-HT-A5R9-01A (aliquot TCGA-HT-A5R9-01A-11D-A289-08) from TCGA case TCGA-HT-A5R9, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.7 years (17,775 days).
Specimen TCGA-HT-A5R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a5b58f2-7f33-423d-bd09-0ee243c0960c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A5R9-10A (Blood Derived Normal), aliquot TCGA-HT-A5R9-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47db1a3f-935f-4f16-80e3-29b7e6ccf38e

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, In Frame Del 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 43/102 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1057519906, COSV57468942, COSV57468989, COSV57477941; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as rs779069001, COSV63639910; called by muse, mutect2, varscan2
- ADGRG7 | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs767327341, COSV56296608; called by muse, mutect2, varscan2
- DDX4 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs137993034; called by muse, varscan2
- GIGYF2 | c.3697G>A p.G1233R | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1430168685, COSV65249417; called by muse, mutect2
- HDHD3 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV53057161; called by muse, mutect2, varscan2
- KCNH4 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs369685674; called by muse, mutect2, varscan2
- KDM5B | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as rs767953294, COSV52507730; called by muse, mutect2, varscan2
- LYPLA1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV57604553; called by muse, mutect2
- MYO15A | c.7267G>A p.G2423S | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs530783345, COSV52755692, COSV52756702; called by muse, mutect2, varscan2
- MYO5B | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 127/372 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs765665080, COSV53217846; called by muse, mutect2, varscan2
- NLRP7 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 154/227 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs777715559, COSV60174445; called by muse, mutect2, varscan2
- NOS1AP | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as rs748601265, COSV62634962; called by muse, mutect2, varscan2
- NOTCH3 | c.6601C>T p.P2201S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV54634775; called by muse, mutect2, varscan2
- NPY | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1388032616, COSV54215104; called by muse, mutect2
- OR6K2 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763965960, COSV62743480; called by muse, mutect2, varscan2
- PASD1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.428); catalogued as COSV64855278; called by muse, mutect2, varscan2
- RBFOX1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs767917479, COSV60955010; called by muse, mutect2, varscan2
- REV1 | c.1200_1202del p.V401del | In Frame Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs777315177; called by pindel, varscan2
- SERPINH1 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV63998029; called by muse, mutect2, varscan2
- SOCS6 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV101205858, COSV67546396; called by muse, mutect2, varscan2
- SP6 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV60617505; called by muse, mutect2, varscan2
- SUCO | c.1867A>G p.I623V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs771766598, COSV55265351, COSV99743691; called by muse, mutect2, varscan2
- TAMM41 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1559338572, COSV56071772; called by muse, mutect2, varscan2
- TCF7L2 | c.1039_1041del p.K347del (on ENST00000355995 / NM_001367943.1; = p.K324del on NM_030756.5) | In Frame Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs745724662; called by pindel, varscan2
- UPF1 | c.2122C>T p.R708C (on ENST00000599848 / NM_001297549.2; = p.R697C on NM_002911.4) | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53196592; called by muse, mutect2, varscan2
- CIC | c.4551_4553del p.K1517_I1518delinsN | In Frame Del (DEL) | VAF 40/74 reads (54%) | called by mutect2, pindel, varscan2
- RBBP7 | c.161+2_161+5del p.X54_splice | Splice Site (DEL) | VAF 32/82 reads (39%) | called by pindel, varscan2
- RBPJ | c.589_592del p.T197Lfs*8 | Frame Shift Del (DEL) | VAF 34/65 reads (52%) | called by pindel, varscan2
- BCL11B | c.1749G>A p.A583= (on ENST00000357195 / NM_001282237.2; = p.A512= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs760702497, COSV61735564; called by muse, mutect2, varscan2
- IPO4 | c.2502C>T p.H834= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs767137886, COSV61016614; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.699C>A p.P233= (on ENST00000485419 / NM_001197113.1; = p.P157= on NM_014575.3) | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV61845341; called by muse, mutect2, varscan2
- MAPKAPK2 | c.696A>C p.P232= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV54316033; called by muse, mutect2, varscan2
- PML | c.318C>T p.N106= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV51446389; called by muse, mutect2
- TRPM2 | c.183G>A p.S61= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs769258683, COSV55969689; called by muse, mutect2, varscan2
- ZNF264 | c.1092T>C p.T364= | Silent (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
